Somatic mutation profile of tumor specimen TCGA-5T-A9QA-01A (aliquot TCGA-5T-A9QA-01A-11D-A41F-09) from TCGA case TCGA-5T-A9QA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.1 years (19,031 days).
Specimen TCGA-5T-A9QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cecaa823-af6d-41ca-a54e-acf7a6a9188a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5T-A9QA-10A (Blood Derived Normal), aliquot TCGA-5T-A9QA-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7499d94d-18ef-4eff-891c-bb610f778846

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 14, Nonsense Mutation 3, Splice Site 2, Splice Region 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99490847; called by muse, mutect2
- AFTPH | c.2215-1G>T p.X739_splice | Splice Site (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99481052; called by muse, mutect2
- CARD11 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV101210848; called by muse, mutect2, varscan2
- CCDC105 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs756991217, COSV99480042; called by muse, mutect2, varscan2
- CLEC1B | c.63C>T p.S21= | Splice Region (SNP) | VAF 25/51 reads (49%) | catalogued as rs753747323, COSV100046153; called by muse, mutect2, varscan2
- CRHR2 | c.918-1G>T p.X306_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as rs1249113179, COSV100530117, COSV59264609; called by muse, mutect2, varscan2
- CUL4A | c.281G>C p.C94S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100417463, COSV58371290; called by muse, mutect2, varscan2
- EVPL | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs201637285, COSV101646200; called by mutect2, varscan2
- FAM217B | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100674611; called by muse, mutect2
- FMNL3 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99526780; called by muse, mutect2, varscan2
- GAS2L1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.258); catalogued as rs772163549, COSV99329647; called by muse, mutect2, varscan2
- GNAI2 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99807199; called by muse, mutect2, varscan2
- KBTBD4 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100442936; called by muse, mutect2, varscan2
- MAGI3 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289996; called by muse, mutect2
- MAP3K15 | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100135385; called by muse, mutect2, varscan2
- OR6B1 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101281642; called by muse, mutect2
- OR9G1 | c.141G>T p.L47F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56449292, COSV56453655; called by muse, mutect2, varscan2
- PLXNA3 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs782513504, COSV63754636, COSV63755502; called by muse, mutect2, varscan2
- RASA3 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as rs769510463, COSV100481055; called by muse, mutect2, varscan2
- RBM19 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV99926621; called by muse, mutect2, varscan2
- RREB1 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100619707; called by muse, mutect2
- SLC25A23 | c.903G>A p.E301= | Splice Region (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99902505; called by muse, mutect2, varscan2
- SLC26A9 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536644; called by muse, mutect2, varscan2
- TGFB3 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99472658; called by muse, mutect2, varscan2
- TMEM144 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99646935; called by muse, mutect2, varscan2
- UPK1A | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99722018; called by muse, mutect2
- USP53 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99917967; called by muse, mutect2, varscan2
- ZNF536 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs941188446, COSV100835611; called by muse, mutect2, varscan2
- CLEC1A | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- MUC16 | c.26446C>A p.H8816N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.851); called by mutect2, varscan2
- AFF3 | c.3387C>T p.S1129= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1214305438, COSV100419774; called by muse, mutect2, varscan2
- CCSER1 | c.1224A>G p.K408= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1434901251, COSV61439941; called by muse, mutect2
- DXO | c.390G>A p.T130= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs758308469, COSV100514809; called by muse, mutect2, varscan2
- FAT4 | c.9063G>T p.V3021= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100629664; called by muse, mutect2, varscan2
- FSHR | c.1443G>A p.V481= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1362038315, COSV100437739; called by muse, mutect2, varscan2
- GPRASP2 | c.828C>G p.A276= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100176899, COSV59991348; called by muse, mutect2, varscan2
- KLB | c.1719C>T p.P573= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs142400043, COSV57301272; called by muse, mutect2, varscan2
- NLRP12 | c.1395G>A p.A465= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PLXNB1 | c.369C>A p.R123= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- POU4F2 | c.570C>T p.G190= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1396766602, COSV99850725; called by muse, mutect2, varscan2
- SFMBT1 | c.2043C>A p.R681= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV56257215, COSV99966315; called by muse, mutect2
- TMEM176A | c.39C>T p.A13= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs775841363, COSV99133910; called by muse, mutect2, varscan2
- WNT11 | c.474G>A p.A158= | Silent (SNP) | VAF 45/277 reads (16%) | catalogued as rs1296478145, COSV100490430; called by muse, mutect2, varscan2
- XAGE5 | c.81T>C p.S27= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs1556777596, COSV100657849; called by muse, mutect2, varscan2
- ADAD2 | c.419-334G>A | Intron (SNP) | VAF 33/50 reads (66%) | catalogued as rs571312243, COSV51893037, COSV51893690; called by muse, mutect2, varscan2
- MIR509-2 | n.50A>T | RNA (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
